EXCEPTIONAL_RESPONDERS case ER-B0HF — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4b386de5-2c5a-47d0-8fc8-67320abe0e9c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1959; Vital status: Alive.

Diagnoses (2)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.0 years (20,820 days); AJCC pathologic stage: Stage IB.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Cardia, NOS; Classification of tumor: primary; Age at diagnosis: 53.6 years (19,594 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Days to last follow up: 1,673 days (4.6 years); Days to best overall response: 374 days (1.0 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Capecitabine + Epirubicin Hydrochloride + Oxaliplatin; Days to treatment start: 245 days; Days to treatment end: 602 days (1.6 years).

Follow-up (1 entry)
- Days to follow up: 1,673 days (4.6 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 1,673 days (4.6 years); Days to recurrence: -20 days.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0HF-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0HF-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-B0HF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0HF-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
